CCG case CUPP-B7G2 — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/db134a28-42ab-4d8d-9d49-7acb9a2343fa

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 43 years; Vital status: Dead; Days to death: 1,961 days (5.4 years); Year of death: 2002; Cause of death: Not Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C80.9; Tissue or organ of origin: Unknown primary site; Classification of tumor: primary; Year of diagnosis: 1996; Tumor grade: G3; Prior malignancy: no; Prior treatment: No.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: First-Line Therapy.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Treatment anatomic sites: Regional Site.
   Recorded as not given: first-line therapy Hormone Therapy; first-line therapy Immunotherapy (Including Vaccines); first-line therapy Pharmaceutical Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 1,961 days (5.4 years); Year of follow up: 2002.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B7G2-TTM1-A: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B7G2-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 35; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 25; Percent monocyte infiltration: 8; Percent neutrophil infiltration: 2.
